Somatic mutation profile of tumor specimen C3N-00492-04 (aliquot CPT0079180009) from CPTAC case C3N-00492, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 49.3 years (17,993 days).
Specimen C3N-00492-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e7e5a1f-be73-4de3-9637-3d38fb8e7272.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00492-31 (Blood Derived Normal), aliquot CPT0012820002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e601d0c1-2769-46d9-9620-a0a13dbd8076

The open-access MAF lists 32 somatic variants for this specimen: 21 protein-altering or splice-affecting, 6 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 6, Splice Region 3, Intron 3, Frame Shift Del 2, 3'Flank 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.799C>T p.R267W | Missense Mutation (SNP) | VAF 278/419 reads (66%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.835); catalogued as rs55832599, CM120851, COSV52678166, COSV52736883, COSV52827473; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 72/161 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs955579071; called by muse, mutect2, varscan2
- COL1A2 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 81/290 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs780355349; called by muse, mutect2, varscan2
- ILVBL | c.518_519del p.C173* | Frame Shift Del (DEL) | VAF 96/295 reads (33%) | catalogued as rs761269390; called by mutect2, pindel, varscan2
- LRRC6 | c.10+6C>T | Splice Region (SNP) | VAF 26/44 reads (59%) | catalogued as rs774104305; called by muse, mutect2, varscan2
- LRRC75A | c.571G>A p.E191K (on ENST00000470794 / NM_001113567.3; = p.G152E on NM_207387.4) | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV63358997; called by muse, mutect2
- MYLK | c.4445T>C p.V1482A | Missense Mutation (SNP) | VAF 188/432 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as rs746820711, COSV60605766; called by muse, mutect2, varscan2
- PCDHA12 | c.1492C>T p.R498W | Missense Mutation (SNP) | VAF 62/1054 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.413); catalogued as rs781890307, COSV56478222; called by muse, mutect2
- SLC34A3 | c.1338C>T p.V446= | Splice Region (SNP) | VAF 77/244 reads (32%) | catalogued as rs574491402; called by muse, mutect2, varscan2
- STARD8 | c.2010C>T p.L670= | Splice Region (SNP) | VAF 63/94 reads (67%) | catalogued as COSV52928940; called by muse, mutect2, varscan2
- TNC | c.1543C>G p.Q515E | Missense Mutation (SNP) | VAF 99/337 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as rs764579107; called by muse, mutect2, varscan2
- TSPAN11 | c.577G>A p.G193S | Missense Mutation (SNP) | VAF 63/141 reads (45%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.954); catalogued as rs768375131, COSV53819465; called by muse, mutect2, varscan2
- TUBAL3 | c.614C>T p.T205M | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs148106464, COSV66814150; called by muse, mutect2
- ZMAT4 | c.193-1G>A p.X65_splice | Splice Site (SNP) | VAF 37/90 reads (41%) | catalogued as COSV52695904; called by muse, mutect2
- C1QL2 | c.626T>A p.I209N | Missense Mutation (SNP) | VAF 251/369 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- FN1 | c.3164A>G p.N1055S | Missense Mutation (SNP) | VAF 24/358 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.1); called by muse, mutect2
- GRIN2B | c.99del p.S34Afs*38 | Frame Shift Del (DEL) | VAF 88/233 reads (38%) | called by mutect2, varscan2
- PITPNM2 | c.3352G>A p.A1118T | Missense Mutation (SNP) | VAF 110/358 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEC24A | c.1698G>C p.Q566H | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- SETD1A | c.3179C>T p.S1060F | Missense Mutation (SNP) | VAF 82/188 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- TARDBP | c.1037A>G p.Q346R | Missense Mutation (SNP) | VAF 58/81 reads (72%) | SIFT tolerated (0.11); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- DHX34 | c.1860C>T p.R620= | Silent (SNP) | VAF 12/326 reads (4%) | called by muse, mutect2
- IRGQ | c.1404C>T p.S468= | Silent (SNP) | VAF 93/216 reads (43%) | catalogued as rs1326877002; called by muse, mutect2, varscan2
- MUC22 | c.2976C>T p.S992= | Silent (SNP) | VAF 230/336 reads (68%) | catalogued as rs753480658; called by mutect2, varscan2
- NRXN2 | c.2019G>A p.L673= | Silent (SNP) | VAF 53/142 reads (37%) | called by muse, mutect2, varscan2
- RAB11FIP1 | c.66G>T p.V22= | Silent (SNP) | VAF 61/178 reads (34%) | called by muse, mutect2, varscan2
- ZFR2 | c.2055G>A p.T685= | Silent (SNP) | VAF 28/282 reads (10%) | catalogued as rs367706746; called by muse, mutect2
- CA10 | c.61+22826A>G | Intron (SNP) | VAF 10/181 reads (6%) | called by muse, mutect2
- CACNA1F | c.4986+49G>A | Intron (SNP) | VAF 15/76 reads (20%) | catalogued as COSV100545025; called by muse, mutect2, varscan2
- CMSS1 | chr3:100185765 C>T | 3'Flank (SNP) | VAF 97/274 reads (35%) | catalogued as rs947753861; called by muse, mutect2, varscan2
- RAB35 | c.*722C>T | 3'UTR (SNP) | VAF 130/412 reads (32%) | catalogued as rs1023111136; called by muse, mutect2, varscan2
- SMOX | c.1531-451G>A | Intron (SNP) | VAF 66/153 reads (43%) | catalogued as rs867290383; called by muse, mutect2, varscan2
